Somatic mutation profile of tumor specimen TCGA-10-0926-01A (aliquot TCGA-10-0926-01A-01W-0420-08) from TCGA case TCGA-10-0926, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.8 years (23,307 days).
Specimen TCGA-10-0926-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3398d5f-d8ce-4ba6-b3cc-1d2a2eae27e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-10-0926-11A (Solid Tissue Normal), aliquot TCGA-10-0926-11A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1437c6c-7ab6-449e-a814-edd6689989ba

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Silent 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 302/360 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CLSPN | c.3992G>A p.R1331Q | Missense Mutation (SNP) | VAF 185/596 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs115320551, COSV52056680; called by muse, mutect2, varscan2
- COL4A6 | c.1643C>A p.P548Q | Missense Mutation (SNP) | VAF 138/366 reads (38%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.803); catalogued as COSV57880840; called by muse, mutect2, varscan2
- CYP27A1 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 127/216 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV51470562; called by muse, mutect2, varscan2
- EIF4EBP1 | c.291C>A p.H97Q | Missense Mutation (SNP) | VAF 92/306 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV58775297; called by muse, mutect2, varscan2
- EXO1 | c.1331A>C p.K444T | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV62220300; called by muse, mutect2, varscan2
- FCGBP | c.11672G>A p.R3891H | Missense Mutation (SNP) | VAF 103/204 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs780105651; called by muse, mutect2, varscan2
- HBD | c.120G>C p.Q40H | Missense Mutation (SNP) | VAF 56/298 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as rs281864505, COSV53083864; called by muse, mutect2, varscan2
- HOXA9 | c.496A>G p.R166G | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100604361, COSV100604395; called by muse, mutect2, varscan2
- HUWE1 | c.11120T>A p.L3707Q | Missense Mutation (SNP) | VAF 277/703 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53366644; called by muse, mutect2, varscan2
- LAMA2 | c.7994C>T p.A2665V | Missense Mutation (SNP) | VAF 147/325 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.111); catalogued as COSV70356517; called by muse, mutect2, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 32/130 reads (25%) | catalogued as rs754860965; called by mutect2, varscan2
- PKN2 | c.2659A>G p.I887V | Missense Mutation (SNP) | VAF 155/536 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.206); catalogued as rs370637742; called by muse, mutect2, varscan2
- SALL1 | c.196A>C p.T66P | Missense Mutation (SNP) | VAF 175/435 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV51765369; called by muse, mutect2, varscan2
- ST8SIA1 | c.790A>G p.K264E | Missense Mutation (SNP) | VAF 108/1468 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV99682941; called by muse, mutect2
- TEX11 | c.1964T>C p.M655T (on ENST00000344304; = p.M640T on NM_031276.3) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV60240373; called by muse, mutect2, varscan2
- ATP6V0A2 | c.744C>T p.H248= | Silent (SNP) | VAF 114/610 reads (19%) | catalogued as rs144293398; called by muse, mutect2, varscan2
- CAMK2A | c.573G>A p.G191= | Silent (SNP) | VAF 12/172 reads (7%) | catalogued as rs373849502; called by muse, mutect2
- LCAT | c.1050C>A p.I350= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99862915; called by muse, mutect2
- SLC10A2 | c.600G>A p.A200= | Silent (SNP) | VAF 188/419 reads (45%) | catalogued as rs749760245, COSV55358990; called by muse, mutect2, varscan2
- UNC79 | c.5904A>G p.P1968= (on ENST00000393151 / NM_001346218.2; = p.P1791= on NM_020818.5) | Silent (SNP) | VAF 142/338 reads (42%) | catalogued as rs1358512261, COSV56415912; called by muse, mutect2, varscan2
